Somatic mutation profile of tumor specimen C3N-01650-06 (aliquot CPT0380400009) from CPTAC case C3N-01650, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 61.4 years (22,437 days).
Specimen C3N-01650-06: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95cfe81e-5424-4dca-a909-01ed4976c39c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01650-71 (Blood Derived Normal), aliquot CPT0405290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab00c647-33f4-442b-901b-8119a14cb55c

The open-access MAF lists 83 somatic variants for this specimen: 59 protein-altering or splice-affecting, 13 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 13, Frame Shift Del 6, Intron 5, Nonsense Mutation 4, 3'UTR 3, 5'Flank 2, Splice Site 2, Frame Shift Ins 2, RNA 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATK | c.3395G>A p.R1132Q (on ENST00000326724 / NM_001080395.3; = p.R1029Q on NM_004920.2) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs777262558; called by muse, mutect2, varscan2
- BST1 | c.390C>A p.S130R | Missense Mutation (SNP) | VAF 27/283 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.059); catalogued as rs141815955; called by muse, mutect2
- CDH11 | c.639G>C p.Q213H | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV51770250; called by muse, mutect2, varscan2
- CYP26B1 | c.1334A>G p.H445R | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs775163285; called by muse, mutect2
- ERN1 | c.2215G>T p.A739S | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs755040095, COSV70501307; called by muse, mutect2, varscan2
- EXPH5 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.331); catalogued as COSV99761949; called by muse, mutect2
- FLT1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 19/221 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs974445913, COSV56719176; called by muse, mutect2
- FSIP2 | c.7793G>C p.R2598T | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100555799; called by muse, mutect2, varscan2
- FSTL5 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV60233745; called by muse, mutect2, varscan2
- GKAP1 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as rs766306669; called by mutect2, varscan2
- GSTA4 | c.273-1G>T p.X91_splice | Splice Site (SNP) | VAF 22/244 reads (9%) | catalogued as COSV100919763; called by muse, mutect2
- L1CAM | c.3616G>A p.D1206N | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100648821; called by muse, mutect2
- LINGO4 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs865835181; called by muse, mutect2, varscan2
- METTL21A | c.622G>T p.E208* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV55881351; called by muse, mutect2, varscan2
- NAT2 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV54062964; called by muse, mutect2, varscan2
- NLRC4 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 46/249 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.478); catalogued as rs750900085, COSV61592260; called by muse, mutect2, varscan2
- PDE3A | c.3059G>T p.G1020V | Missense Mutation (SNP) | VAF 46/403 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62980424; called by muse, mutect2, varscan2
- PIK3C2G | c.2164C>A p.R722S (on ENST00000676171; = p.R681S on NM_004570.5) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56823595, COSV56829183; called by muse, mutect2, varscan2
- PUM3 | c.1166C>G p.T389S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs760902576; called by muse, mutect2, varscan2
- SCN2A | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV51847574, COSV51855395; called by muse, mutect2, varscan2
- VHL | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 92/336 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs5030821, CM114580, CM941382, COSV56547786, COSV56550604; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AATK | c.2459del p.P820Lfs*25 (on ENST00000326724 / NM_001080395.3; = p.P717Lfs*25 on NM_004920.2) | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- ANKRD34C | c.293G>A p.G98E | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD63 | c.359C>G p.P120R | Missense Mutation (SNP) | VAF 83/441 reads (19%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- ARL6IP4 | c.555G>T p.M185I | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ATP2A3 | c.1795A>T p.M599L | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- BAP1 | c.69del p.V24Sfs*48 | Frame Shift Del (DEL) | VAF 83/408 reads (20%) | called by mutect2, pindel, varscan2
- BCL7B | c.-23_6del | Translation Start Site (DEL) | VAF 21/120 reads (18%) | called by mutect2, pindel
- CARNS1 | c.2015G>A p.G672E | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC63 | c.175C>A p.Q59K | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- COG8 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 42/446 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2
- CSMD3 | c.10210C>A p.P3404T (on ENST00000297405 / NM_001363185.1; = p.P3235T on NM_052900.3) | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- CWC22 | c.1226del p.G409Efs*34 | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | called by mutect2, pindel, varscan2
- CYP7A1 | c.596A>T p.K199I | Missense Mutation (SNP) | VAF 92/538 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- DKC1 | c.1327A>G p.K443E | Missense Mutation (SNP) | VAF 78/493 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNASE1L1 | c.-88+1G>T | Splice Site (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- FLCN | c.635A>C p.Q212P | Missense Mutation (SNP) | VAF 99/524 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- FSCN1 | c.41del p.F14Sfs*11 | Frame Shift Del (DEL) | VAF 20/124 reads (16%) | called by mutect2, pindel
- GAS2L1 | c.1616C>G p.T539S | Missense Mutation (SNP) | VAF 75/315 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- H2AC4 | c.176T>A p.L59Q | Missense Mutation (SNP) | VAF 23/393 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- HP1BP3 | c.436A>G p.R146G | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- IGF2 | c.398T>C p.L133P (on ENST00000434045 / NM_001127598.3; = p.L77P on NM_000612.6) | Missense Mutation (SNP) | VAF 51/249 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- LGALS4 | c.7T>C p.Y3H | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- LYST | c.3261A>C p.E1087D | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPAT | c.2293G>T p.G765* | Nonsense Mutation (SNP) | VAF 18/204 reads (9%) | called by muse, mutect2
- NR4A1 | c.147G>C p.W49C (on ENST00000545748 / NM_001202234.1; = p.W8C on NM_001202233.1) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PA2G4 | c.247_248dup p.N83Kfs*11 | Frame Shift Ins (INS) | VAF 28/137 reads (20%) | called by mutect2, pindel, varscan2
- PEX12 | c.468_471dup p.A158Qfs*61 | Frame Shift Ins (INS) | VAF 49/305 reads (16%) | called by mutect2, pindel, varscan2
- POM121 | c.637del p.S213Pfs*13 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- RGS22 | c.601T>C p.Y201H | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- RIPOR2 | c.2619_2620del p.S874Lfs*24 | Frame Shift Del (DEL) | VAF 12/107 reads (11%) | called by mutect2, pindel, varscan2
- SEMA4A | c.1548G>A p.W516* | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2
- SH2D3A | c.1530C>A p.D510E | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.042); called by muse, mutect2
- SLC30A9 | c.419T>A p.F140Y | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.115); called by muse, varscan2
- SLC5A1 | c.1196A>G p.N399S | Missense Mutation (SNP) | VAF 43/506 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2
- STKLD1 | c.1925A>T p.E642V | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- WIPF2 | c.980C>G p.P327R | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- ZFAT | c.2686C>T p.L896F | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- ZSWIM8 | c.1087A>G p.S363G | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ANKLE2 | c.2790G>A p.A930= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as rs984225308; called by muse, mutect2, varscan2
- CHMP1B | c.288T>A p.V96= | Silent (SNP) | VAF 18/162 reads (11%) | called by muse, mutect2, varscan2
- CREB3L1 | c.471G>A p.P157= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as rs369699514; called by muse, mutect2, varscan2
- DNAH9 | c.12543G>A p.P4181= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as rs571913392, COSV52346856; called by muse, mutect2, varscan2
- MICAL2 | c.1128C>T p.A376= | Silent (SNP) | VAF 22/326 reads (7%) | called by muse, mutect2
- OR52W1 | c.202T>C p.L68= | Silent (SNP) | VAF 24/225 reads (11%) | called by muse, mutect2, varscan2
- RAPGEF1 | c.2274G>A p.T758= | Silent (SNP) | VAF 37/186 reads (20%) | catalogued as rs376156893; called by muse, mutect2, varscan2
- SCUBE1 | c.1722A>G p.A574= | Silent (SNP) | VAF 79/348 reads (23%) | called by muse, mutect2, varscan2
- SFSWAP | c.594T>C p.S198= | Silent (SNP) | VAF 22/178 reads (12%) | called by muse, varscan2
- SLC43A1 | c.1524G>A p.E508= | Silent (SNP) | VAF 32/115 reads (28%) | called by muse, mutect2
- THSD7B | c.1068T>C p.S356= | Silent (SNP) | VAF 74/374 reads (20%) | called by muse, mutect2, varscan2
- USP49 | c.843C>T p.F281= | Silent (SNP) | VAF 55/262 reads (21%) | called by muse, mutect2, varscan2
- USP5 | c.2322C>A p.I774= (on ENST00000229268 / NM_001098536.2; = p.I751= on NM_003481.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 44/169 reads (26%) | called by muse, mutect2, varscan2
- ACTN3 | chr11:66546683 C>A | 5'Flank (SNP) | VAF 60/360 reads (17%) | called by muse, mutect2, varscan2
- AL590867.2 | n.427G>A | RNA (SNP) | VAF 12/144 reads (8%) | catalogued as rs1288831934; called by muse, mutect2
- APOBEC3B | c.*33A>T | 3'UTR (SNP) | VAF 11/132 reads (8%) | called by muse, mutect2, varscan2
- DBI | c.9+522G>A | Intron (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- EIF4A1 | c.997-100C>G | Intron (SNP) | VAF 51/264 reads (19%) | called by muse, mutect2, varscan2
- FAM193A | chr4:2625293 G>T | 5'Flank (SNP) | VAF 15/197 reads (8%) | called by muse, mutect2
- NAV3 | c.6519-231G>A | Intron (SNP) | VAF 9/55 reads (16%) | catalogued as rs962927581; called by muse, mutect2, varscan2
- PIF1 | c.*487C>T | 3'UTR (SNP) | VAF 34/323 reads (11%) | called by muse, mutect2, varscan2
- PRR29 | c.471-22del | Intron (DEL) | VAF 11/58 reads (19%) | called by mutect2, pindel, varscan2
- SCUBE1 | c.727+2730G>T | Intron (SNP) | VAF 21/205 reads (10%) | called by muse, mutect2
- STOX1 | c.*37G>A | 3'UTR (SNP) | VAF 28/109 reads (26%) | catalogued as rs750691764; called by muse, mutect2
